Somatic mutation profile of tumor specimen MMRF_2727_1_BM_CD138pos (aliquot MMRF_2727_1_BM_CD138pos_T1_KHS5U_L14865) from MMRF case MMRF_2727, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.5 years (17,712 days).
Specimen MMRF_2727_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcc08725-cbc8-41ec-8c4f-521378d1c727.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2727_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2727_1_PB_WBC_C3_KHS5U_L14866; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daa567ed-b4a5-41a7-80cc-f90e88f36da6

The open-access MAF lists 74 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 21, Silent 7, Intron 4, 5'Flank 3, 3'Flank 2, Nonstop Mutation 1, RNA 1, Frame Shift Del 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 44/117 reads (38%) | catalogued as rs561778796, COSV100517144; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 119/318 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BDKRB2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs772874206, COSV100021300, COSV60016124; called by muse, mutect2, varscan2
- CCDC65 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748450007; called by muse, mutect2, varscan2
- CNRIP1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 212/460 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs760897836; called by muse, mutect2, varscan2
- CNTNAP2 | c.3356G>A p.R1119H | Missense Mutation (SNP) | VAF 124/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774709566, CM080156, COSV100668360, COSV62191661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNER | c.2064C>A p.S688R | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV59167286; called by muse, mutect2, varscan2
- ERCC4 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 75/129 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100318806; called by muse, mutect2, varscan2
- IGLV3-1 | c.277A>T p.I93F | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs548457166; called by muse, mutect2, varscan2
- KDM4B | c.1697C>A p.S566Y | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs760760991; called by muse, mutect2, varscan2
- KIAA1671 | c.2042C>T p.T681M | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs955078332, COSV64447798; called by muse, mutect2, varscan2
- LIFR | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 177/500 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs765499626, COSV54692351; called by muse, mutect2, varscan2
- OR8J1 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 188/356 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV57320084; called by muse, mutect2, varscan2
- POLR3C | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs367900792; called by muse, mutect2, varscan2
- SORCS2 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.546); catalogued as rs777217650, COSV61161977, COSV61165627; called by muse, mutect2, varscan2
- CELSR1 | c.8084C>T p.P2695L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD2 | c.2588T>A p.F863Y | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPB1 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNND1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CXXC4 | c.601T>G p.L201V | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DGAT2L6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 255/270 reads (94%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMO3 | c.732G>C p.K244N | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KRTAP25-1 | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 25/840 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2
- LRRD1 | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 119/177 reads (67%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTRF1 | c.1198A>T p.I400L | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- P4HA3 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEC | c.5633_5648del p.R1878Pfs*172 (on ENST00000322810 / NM_201380.4; = p.R1768Pfs*172 on NM_000445.5) | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by mutect2, varscan2
- RIOK2 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- SLC44A5 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- SPIDR | c.303G>C p.W101C | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, varscan2
- TENM1 | c.443A>C p.D148A | Missense Mutation (SNP) | VAF 248/256 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNK2 | c.1763C>G p.S588C | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- USP1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- USP19 | c.3956G>C p.*1319Sext*53 | Nonstop Mutation (SNP) | VAF 75/251 reads (30%) | called by muse, mutect2, varscan2
- ZMYM4 | c.2286T>A p.H762Q | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ALDH16A1 | c.1368C>G p.G456= | Silent (SNP) | VAF 61/207 reads (29%) | catalogued as COSV53197106; called by muse, mutect2, varscan2
- ASPG | c.1377C>T p.D459= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs370329881; called by muse, mutect2, varscan2
- BAIAP2L2 | c.816C>T p.S272= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs769703272; called by muse, mutect2, varscan2
- IGHV2-70 | c.297G>A p.V99= | Silent (SNP) | VAF 79/117 reads (68%) | catalogued as rs138072391; called by muse, varscan2
- KCTD17 | c.261C>T p.P87= | Silent (SNP) | VAF 78/145 reads (54%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.1188A>T p.I396= | Silent (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- RASA3 | c.1071C>T p.S357= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as rs1194835316; called by muse, mutect2, varscan2
- ABCG1 | c.*189T>A | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- AP5M1 | c.*705G>T | 3'UTR (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- AR | c.*2963G>A | 3'UTR (SNP) | VAF 75/75 reads (100%) | catalogued as rs777700162; called by muse, mutect2, varscan2
- BCL7A | chr12:122020995 C>T | 5'Flank (SNP) | VAF 82/164 reads (50%) | catalogued as COSV55849233, COSV55850852; called by muse, mutect2, varscan2
- BMP6 | c.*582T>G | 3'UTR (SNP) | VAF 69/140 reads (49%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96089529 C>T | 3'Flank (SNP) | VAF 74/155 reads (48%) | called by muse, mutect2, varscan2
- CHCHD7 | c.-17+1033A>G | Intron (SNP) | VAF 127/274 reads (46%) | catalogued as rs1229784934; called by muse, mutect2, varscan2
- CHRNA9 | c.*238G>A | 3'UTR (SNP) | VAF 34/70 reads (49%) | catalogued as rs1018979149; called by muse, mutect2, varscan2
- CTAGE1 | c.*107A>C | 3'UTR (SNP) | VAF 145/319 reads (45%) | catalogued as COSV66943253; called by muse, mutect2, varscan2
- DMAC1 | c.*604A>C | 3'UTR (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- EIF1 | c.*1676G>C | 3'UTR (SNP) | VAF 42/164 reads (26%) | called by muse, mutect2, varscan2
- FNBP4 | c.*716A>G | 3'UTR (SNP) | VAF 38/49 reads (78%) | called by muse, mutect2, varscan2
- HPS1 | c.*446C>T | 3'UTR (SNP) | VAF 57/110 reads (52%) | called by muse, mutect2, varscan2
- KAT7 | chr17:49788542 T>A | 5'Flank (SNP) | VAF 131/429 reads (31%) | called by muse, mutect2, varscan2
- LIMCH1 | c.*1537G>A | 3'UTR (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- LIMD1 | c.*5505G>A | 3'UTR (SNP) | VAF 49/173 reads (28%) | catalogued as rs1432690810; called by muse, mutect2, varscan2
- MDFIC | c.*1499C>A | 3'UTR (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
- MEIS2 | c.*1046A>C | 3'UTR (SNP) | VAF 90/156 reads (58%) | called by muse, mutect2, varscan2
- MGLL | c.*2903T>A | 3'UTR (SNP) | VAF 89/261 reads (34%) | called by muse, mutect2, varscan2
- NBPF22P | n.1164C>G | RNA (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- NPHP4 | c.2305-1010C>T | Intron (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- RHOJ | c.-251T>C | 5'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- SESTD1 | c.*3710G>A | 3'UTR (SNP) | VAF 83/151 reads (55%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143623346 T>C | 3'Flank (SNP) | VAF 81/81 reads (100%) | called by muse, mutect2, varscan2
- STOML1 | c.133+462C>A | Intron (SNP) | VAF 64/101 reads (63%) | called by muse, mutect2, varscan2
- SYBU | chr8:109645259 G>T | 5'Flank (SNP) | VAF 59/143 reads (41%) | catalogued as rs1345338550; called by muse, mutect2, varscan2
- TCHH | c.*1038G>A | 3'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- UBXN10 | c.*226G>C | 3'UTR (SNP) | VAF 97/204 reads (48%) | catalogued as rs780706873; called by muse, mutect2, varscan2
- UNC45B | c.*1918T>G | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- USP19 | c.*150A>T | 3'UTR (SNP) | VAF 55/173 reads (32%) | called by muse, mutect2, varscan2
- USP19 | c.*149G>C | 3'UTR (SNP) | VAF 53/169 reads (31%) | called by muse, mutect2, varscan2
- ZBTB17 | c.1372-133A>C | Intron (SNP) | VAF 115/241 reads (48%) | called by muse, mutect2, varscan2
